Somatic mutation profile of tumor specimen MMRF_1928_1_BM_CD138pos (aliquot MMRF_1928_1_BM_CD138pos_T1_KBS5U_L07249) from MMRF case MMRF_1928, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 53.2 years (19,425 days).
Specimen MMRF_1928_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5ca47e6e-d255-4c72-ab65-b6d30c84a928.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1928_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1928_1_PB_Whole_C3_KBS5U_L07250; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/423e3eae-2a7a-4d83-a46c-3fe800d5842c

The open-access MAF lists 144 somatic variants for this specimen: 52 protein-altering or splice-affecting, 17 silent, 75 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 43, 3'UTR 38, Intron 20, Silent 17, 5'UTR 8, 3'Flank 4, 5'Flank 4, Nonsense Mutation 2, In Frame Del 2, Frame Shift Ins 2, Frame Shift Del 2, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BCAM | c.1747C>T p.R583W | Missense Mutation (SNP) | VAF 16/109 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.329); catalogued as rs750550926, COSV54301352; called by muse, mutect2, varscan2
- C1orf158 | c.539C>T p.A180V | Missense Mutation (SNP) | VAF 109/210 reads (52%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.904); catalogued as rs151163969; called by muse, mutect2, varscan2
- CD5L | c.569G>A p.R190H | Missense Mutation (SNP) | VAF 58/344 reads (17%) | SIFT tolerated (0.56); PolyPhen possibly damaging (0.493); catalogued as rs937449814; called by muse, mutect2, varscan2
- CDH23 | c.4078G>A p.A1360T | Missense Mutation (SNP) | VAF 21/270 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.575); catalogued as COSV56486751; called by muse, mutect2
- CLCN1 | c.2662C>T p.R888W | Missense Mutation (SNP) | VAF 41/157 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs781320829, CD1210521; called by muse, mutect2, varscan2
- CYLC2 | c.529G>C p.E177Q | Missense Mutation (SNP) | VAF 60/175 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.93); catalogued as COSV100872297; called by muse, mutect2, varscan2
- DIPK1B | c.746G>A p.R249H | Missense Mutation (SNP) | VAF 28/132 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as rs199954394, COSV100765486; called by muse, mutect2, varscan2
- IGHV2-70 | c.138C>G p.F46L | Missense Mutation (SNP) | VAF 68/68 reads (100%) | SIFT tolerated (0.06); PolyPhen benign (0.136); catalogued as rs374979633; called by muse, varscan2
- IGKV3-20 | c.179A>G p.K60R | Missense Mutation (SNP) | VAF 12/12 reads (100%) | SIFT deleterious (0.04); PolyPhen benign (0.034); catalogued as rs529328604; called by muse, varscan2
- IGLV4-3 | c.227G>A p.S76N | Missense Mutation (SNP) | VAF 90/184 reads (49%) | SIFT tolerated (0.38); PolyPhen benign (0.009); catalogued as rs535662906; called by muse, mutect2, varscan2
- INO80 | c.3698G>A p.R1233H | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); catalogued as COSV62742962; called by muse, mutect2, varscan2
- MLPH | c.486C>A p.S162R | Missense Mutation (SNP) | VAF 32/58 reads (55%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.525); catalogued as rs376211913; called by muse, mutect2
- NCOR2 | c.1463G>A p.R488Q | Missense Mutation (SNP) | VAF 25/113 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.975); catalogued as COSV62299668; called by muse, mutect2, varscan2
- OR4K5 | c.154G>A p.D52N | Missense Mutation (SNP) | VAF 158/575 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.049); catalogued as COSV60004008; called by muse, mutect2, varscan2
- RB1 | c.1505_1511del p.T502Rfs*15 | Frame Shift Del (DEL) | VAF 11/25 reads (44%) | catalogued as COSV57320902; called by mutect2, pindel, varscan2
- RESF1 | c.3092A>G p.Y1031C | Missense Mutation (SNP) | VAF 17/164 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.018); catalogued as rs151274990; called by muse, mutect2, varscan2
- RFX4 | c.1204G>T p.D402Y (on ENST00000392842 / NM_213594.3; = p.D308Y on NM_032491.6) | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV57579444; called by muse, mutect2, varscan2
- SF3B3 | c.2696C>T p.T899I | Missense Mutation (SNP) | VAF 12/182 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.039); catalogued as rs11551672, COSV56790963; called by muse, mutect2
- TDRD7 | c.342dup p.L115Sfs*25 | Frame Shift Ins (INS) | VAF 63/326 reads (19%) | catalogued as rs1295303043; called by mutect2, pindel, varscan2
- TM9SF4 | c.1390G>A p.V464I | Missense Mutation (SNP) | VAF 87/177 reads (49%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.591); catalogued as rs1223951369, COSV54110711; called by muse, mutect2, varscan2
- TMEM119 | c.463G>A p.D155N | Missense Mutation (SNP) | VAF 26/103 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as rs572995428, COSV67188317; called by muse, mutect2, varscan2
- ZFR | c.885_905del p.A296_A302del | In Frame Del (DEL) | VAF 37/99 reads (37%) | catalogued as rs771973732; called by mutect2, varscan2
- ADH1C | c.726C>G p.I242M | Missense Mutation (SNP) | VAF 14/449 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); called by muse, mutect2
- C3orf33 | c.851T>G p.L284R (on ENST00000340171 / NM_001308229.2; = p.L241R on NM_173657.2) | Missense Mutation (SNP) | VAF 84/501 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.667); called by muse, mutect2, varscan2
- C3orf52 | c.609T>G p.C203W | Missense Mutation (SNP) | VAF 110/180 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- C3orf85 | c.86C>T p.A29V | Missense Mutation (SNP) | VAF 53/194 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.891); called by muse, mutect2, varscan2
- CDC42BPB | c.2677G>C p.V893L | Missense Mutation (SNP) | VAF 50/51 reads (98%) | SIFT tolerated (0.07); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- CLEC11A | c.963C>A p.F321L | Missense Mutation (SNP) | VAF 74/260 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.207); called by muse, mutect2, varscan2
- DNTTIP1 | c.821T>A p.I274N | Missense Mutation (SNP) | VAF 47/156 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EPB41L4B | c.1081C>T p.H361Y | Missense Mutation (SNP) | VAF 40/142 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.656); called by muse, mutect2, varscan2
- GRIA3 | c.1094G>C p.G365A | Missense Mutation (SNP) | VAF 39/229 reads (17%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.647); called by muse, mutect2, varscan2
- H2BC17 | c.363G>C p.K121N | Missense Mutation (SNP) | VAF 101/231 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- HNRNPCL2 | c.868C>T p.Q290* | Nonsense Mutation (SNP) | VAF 6/136 reads (4%) | called by muse, mutect2
- HYDIN | c.7416G>A p.M2472I | Missense Mutation (SNP) | VAF 5/108 reads (5%) | SIFT tolerated (0.19); PolyPhen benign (0.035); called by muse, mutect2
- IGLL5 | c.106dup p.H36Pfs*56 | Frame Shift Ins (INS) | VAF 22/53 reads (42%) | called by mutect2, pindel, varscan2
- LACC1 | c.397G>A p.D133N | Missense Mutation (SNP) | VAF 36/111 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.521); called by muse, mutect2, varscan2
- NLRC5 | c.1227C>G p.C409W | Missense Mutation (SNP) | VAF 10/224 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- ODR4 | c.485G>A p.R162K | Missense Mutation (SNP) | VAF 35/220 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- PAN3 | c.1569_1573+10del p.X523_splice | Splice Site (DEL) | VAF 14/156 reads (9%) | called by mutect2, pindel
- PGM1 | c.1590G>T p.Q530H | Missense Mutation (SNP) | VAF 43/90 reads (48%) | SIFT tolerated (0.11); PolyPhen benign (0.219); called by muse, mutect2, varscan2
- PGM1 | c.1591G>T p.D531Y | Missense Mutation (SNP) | VAF 43/90 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- PHRF1 | c.1604G>C p.R535T (on ENST00000264555 / NM_001286581.2; = p.R534T on NM_020901.4) | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- RPL38 | c.88G>T p.D30Y | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- RPSA | c.431C>T p.T144I | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.513); called by muse, mutect2, varscan2
- SCN11A | c.619A>T p.I207F | Missense Mutation (SNP) | VAF 16/216 reads (7%) | SIFT tolerated (0.18); PolyPhen benign (0); called by muse, mutect2
- SCO2 | c.791T>C p.V264A | Missense Mutation (SNP) | VAF 33/75 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.022); called by muse, varscan2
- SLC15A3 | c.93del p.R32Gfs*156 | Frame Shift Del (DEL) | VAF 6/24 reads (25%) | called by mutect2, varscan2
- STEAP2 | c.1164G>A p.W388* | Nonsense Mutation (SNP) | VAF 62/233 reads (27%) | called by muse, mutect2, varscan2
- TENM1 | c.2090T>A p.M697K | Missense Mutation (SNP) | VAF 118/171 reads (69%) | SIFT tolerated (0.16); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZDHHC14 | c.1195_1221del p.T399_G407del | In Frame Del (DEL) | VAF 27/72 reads (38%) | called by mutect2, pindel
- ZNF451 | c.132A>C p.E44D | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT tolerated (0.16); PolyPhen benign (0.326); called by muse, mutect2, varscan2
- ZNF716 | c.1134A>T p.K378N | Missense Mutation (SNP) | VAF 45/151 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.227); called by muse, mutect2, varscan2
- ACTN1 | c.30C>T p.N10= | Silent (SNP) | VAF 33/64 reads (52%) | called by muse, mutect2, varscan2
- ARMC3 | c.468C>T p.I156= | Silent (SNP) | VAF 30/90 reads (33%) | called by muse, mutect2, varscan2
- ATP10A | c.4341C>T p.V1447= | Silent (SNP) | VAF 7/126 reads (6%) | called by muse, mutect2
- ATRN | c.193C>T p.L65= | Silent (SNP) | VAF 4/27 reads (15%) | catalogued as rs1398454562, COSV99496489; called by muse, mutect2
- CTNNBL1 | c.1345C>T p.L449= | Silent (SNP) | VAF 9/86 reads (10%) | called by muse, mutect2, varscan2
- DAB1 | c.1404C>A p.S468= (on ENST00000371231; = p.S435= on NM_021080.5 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 14/158 reads (9%) | called by muse, mutect2
- EVX1 | c.108G>A p.P36= | Silent (SNP) | VAF 63/145 reads (43%) | catalogued as COSV56084988; called by muse, mutect2, varscan2
- H3C2 | c.309G>C p.G103= | Silent (SNP) | VAF 82/144 reads (57%) | catalogued as rs763834926, COSV52518313; called by muse, mutect2, varscan2
- IGHV2-70 | c.60G>A p.Q20= | Silent (SNP) | VAF 78/78 reads (100%) | catalogued as rs374015637; called by muse, varscan2
- IGLV3-1 | c.99A>T p.P33= | Silent (SNP) | VAF 72/142 reads (51%) | catalogued as rs373803208; called by muse, varscan2
- NSMCE3 | c.621C>T p.V207= | Silent (SNP) | VAF 61/188 reads (32%) | called by muse, mutect2, varscan2
- PDE3B | c.1494G>T p.L498= | Silent (SNP) | VAF 35/145 reads (24%) | called by muse, mutect2, varscan2
- PECR | c.873A>G p.K291= | Silent (SNP) | VAF 176/375 reads (47%) | called by muse, mutect2, varscan2
- PRR12 | c.2244C>G p.G748= (on ENST00000615927; = p.G1569= on NM_020719.3) | Silent (SNP) | VAF 13/42 reads (31%) | catalogued as rs772254918, COSV101330814; called by muse, mutect2, varscan2
- SLITRK6 | c.639T>A p.L213= | Silent (SNP) | VAF 67/202 reads (33%) | called by muse, mutect2, varscan2
- SSC4D | c.1254T>C p.A418= | Silent (SNP) | VAF 16/31 reads (52%) | called by muse, varscan2
- ZNF462 | c.4563A>C p.P1521= | Silent (SNP) | VAF 80/391 reads (20%) | catalogued as rs776868481; called by muse, mutect2, varscan2
- AC048338.2 | c.*140C>G | 3'UTR (SNP) | VAF 15/36 reads (42%) | catalogued as rs1008627517; called by muse, mutect2, varscan2
- AC048338.2 | c.*139C>A | 3'UTR (SNP) | VAF 15/36 reads (42%) | called by muse, mutect2, varscan2
- ADGRF2 | chr6:47683383 C>A | 3'Flank (SNP) | VAF 27/76 reads (36%) | called by muse, mutect2, varscan2
- AKT3 | c.*2615G>C | 3'UTR (SNP) | VAF 22/117 reads (19%) | catalogued as rs891121367; called by muse, mutect2, varscan2
- ARHGAP12 | c.1951+63C>T | Intron (SNP) | VAF 32/63 reads (51%) | called by muse, mutect2, varscan2
- ARL14 | c.*51T>C | 3'UTR (SNP) | VAF 16/606 reads (3%) | called by muse, mutect2
- ASXL1 | c.-13G>A | 5'UTR (SNP) | VAF 3/49 reads (6%) | called by muse, mutect2
- ATF5 | c.*53C>T | 3'UTR (SNP) | VAF 8/34 reads (24%) | catalogued as rs1296228104; called by muse, mutect2
- BET1 | c.*612G>T | 3'UTR (SNP) | VAF 70/145 reads (48%) | called by muse, mutect2, varscan2
- C20orf173 | c.-213C>T | 5'UTR (SNP) | VAF 160/328 reads (49%) | catalogued as rs375185322; called by muse, mutect2, varscan2
- CDC14A | c.1137+190C>T | Intron (SNP) | VAF 9/90 reads (10%) | called by muse, mutect2, varscan2
- CDH7 | chr18:65883215 A>C | 3'Flank (SNP) | VAF 43/95 reads (45%) | called by muse, mutect2, varscan2
- CEP76 | c.934-16T>G | Intron (SNP) | VAF 49/103 reads (48%) | called by muse, mutect2, varscan2
- CLIP2 | c.*1368C>T | 3'UTR (SNP) | VAF 14/154 reads (9%) | catalogued as rs533274009; called by muse, mutect2
- COA5 | c.*875T>C | 3'UTR (SNP) | VAF 91/193 reads (47%) | called by muse, mutect2, varscan2
- COL6A2 | c.736-69G>A | Intron (SNP) | VAF 8/92 reads (9%) | called by muse, mutect2
- CRB2 | c.*870G>A | 3'UTR (SNP) | VAF 112/343 reads (33%) | called by muse, mutect2, varscan2
- CROCCP2 | n.495+8054C>T | Intron (SNP) | VAF 27/147 reads (18%) | called by muse, mutect2, varscan2
- CSMD1 | chr8:2936210 G>A | 3'Flank (SNP) | VAF 23/72 reads (32%) | called by muse, mutect2, varscan2
- DBF4B | c.*400T>A | 3'UTR (SNP) | VAF 19/211 reads (9%) | called by muse, mutect2
- DDIT4L | c.*926G>T | 3'UTR (SNP) | VAF 11/92 reads (12%) | called by muse, mutect2, varscan2
- DDX31 | c.903+411C>G | Intron (SNP) | VAF 10/177 reads (6%) | called by muse, mutect2
- DNAJB9 | c.*991del | 3'UTR (DEL) | VAF 15/133 reads (11%) | called by mutect2, pindel, varscan2
- EPDR1 | c.-113G>A | 5'UTR (SNP) | VAF 74/209 reads (35%) | called by muse, mutect2, varscan2
- EPPIN | c.*457T>G | 3'UTR (SNP) | VAF 20/106 reads (19%) | called by muse, mutect2, varscan2
- ESR1 | c.*582C>T | 3'UTR (SNP) | VAF 21/74 reads (28%) | catalogued as rs932255037; called by muse, mutect2, varscan2
- FGF18 | c.*711T>C | 3'UTR (SNP) | VAF 10/96 reads (10%) | called by muse, mutect2, varscan2
- FHL1 | c.689-47C>T | Intron (SNP) | VAF 14/48 reads (29%) | catalogued as rs752489174; called by muse, mutect2, varscan2
- FZD5 | c.*2095A>G | 3'UTR (SNP) | VAF 14/120 reads (12%) | catalogued as rs897360542; called by muse, mutect2, varscan2
- GAD2 | c.*34+817C>T | Intron (SNP) | VAF 58/159 reads (36%) | catalogued as rs552756075; called by muse, mutect2, varscan2
- GAPDHS | c.660-84C>T | Intron (SNP) | VAF 22/55 reads (40%) | catalogued as rs1022077845; called by muse, mutect2, varscan2
- GCSAML | c.*824A>T | 3'UTR (SNP) | VAF 19/346 reads (5%) | called by muse, mutect2
- GRIP1 | c.*462_*494del | 3'UTR (DEL) | VAF 61/174 reads (35%) | called by mutect2, pindel
- HPD | c.324+17G>A | Intron (SNP) | VAF 28/234 reads (12%) | catalogued as rs1451577597; called by muse, mutect2, varscan2
- IGHJ6 | chr14:105863428 A>C | 5'Flank (SNP) | VAF 10/10 reads (100%) | catalogued as rs142329401; called by muse, varscan2
- IGHJ6 | chr14:105863441 T>A | 5'Flank (SNP) | VAF 9/9 reads (100%) | called by muse, varscan2
- IMMP2L | c.305+1130T>G | Intron (SNP) | VAF 28/60 reads (47%) | called by muse, mutect2, varscan2
- INO80D | c.*3441G>A | 3'UTR (SNP) | VAF 29/125 reads (23%) | called by muse, mutect2, varscan2
- IRAK4 | c.652-96A>G | Intron (SNP) | VAF 3/10 reads (30%) | catalogued as rs1156665106; called by muse, mutect2
- ITGA1 | c.-114G>A | 5'UTR (SNP) | VAF 5/64 reads (8%) | catalogued as rs1177296163; called by muse, mutect2
- KRT75 | c.-54A>G | 5'UTR (SNP) | VAF 76/166 reads (46%) | called by muse, mutect2, varscan2
- LTB | c.163-30A>T | Intron (SNP) | VAF 207/449 reads (46%) | catalogued as COSV53002619; called by muse, mutect2, varscan2
- LTB | c.162+130C>A | Intron (SNP) | VAF 56/101 reads (55%) | called by muse, mutect2, varscan2
- MAP4K3 | c.919-57A>G | Intron (SNP) | VAF 35/70 reads (50%) | called by muse, mutect2, varscan2
- MARCHF5 | c.*2714C>T | 3'UTR (SNP) | VAF 16/78 reads (21%) | called by mutect2, varscan2
- MET | c.*76C>T | 3'UTR (SNP) | VAF 35/56 reads (63%) | catalogued as rs527496385; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MKI67 | c.*514G>A | 3'UTR (SNP) | VAF 17/129 reads (13%) | called by muse, mutect2, varscan2
- NBPF2P | n.568G>T | RNA (SNP) | VAF 46/258 reads (18%) | called by muse, mutect2
- NFIB | c.*146T>G | 3'UTR (SNP) | VAF 204/300 reads (68%) | called by muse, varscan2
- NSD2 | c.1882-5390A>C | Intron (SNP) | VAF 51/112 reads (46%) | called by muse, mutect2, varscan2
- OR2T2 | chr1:248441845 C>A | 5'Flank (SNP) | VAF 27/134 reads (20%) | called by muse, mutect2, varscan2
- PDP1 | chr8:93916185 G>A | 5'Flank (SNP) | VAF 85/186 reads (46%) | called by muse, mutect2, varscan2
- PFKFB2 | chr1:207080795 T>A | 3'Flank (SNP) | VAF 47/151 reads (31%) | called by muse, mutect2, varscan2
- PGK1 | c.*202C>T | 3'UTR (SNP) | VAF 10/20 reads (50%) | catalogued as rs1357460238; called by muse, mutect2, varscan2
- PHF24 | c.*909T>C | 3'UTR (SNP) | VAF 39/181 reads (22%) | called by muse, mutect2, varscan2
- PMM2 | c.*1444T>C | 3'UTR (SNP) | VAF 64/127 reads (50%) | called by muse, mutect2, varscan2
- POC1B-GALNT4 | c.*359G>T | 3'UTR (SNP) | VAF 43/139 reads (31%) | called by muse, mutect2, varscan2
- PPM1G | c.*2A>C | 3'UTR (SNP) | VAF 83/322 reads (26%) | called by muse, mutect2, varscan2
- PTEN | c.-111G>A | 5'UTR (SNP) | VAF 28/147 reads (19%) | catalogued as rs761148721; called by muse, mutect2, varscan2
- RNF217 | c.*8309A>C | 3'UTR (SNP) | VAF 49/118 reads (42%) | called by muse, mutect2, varscan2
- SAP30L | c.*95T>A | 3'UTR (SNP) | VAF 27/303 reads (9%) | called by muse, mutect2
- SIK1B | c.*1442_*1457del | 3'UTR (DEL) | VAF 11/62 reads (18%) | called by mutect2, pindel
- SIRT2 | c.-73G>A | 5'UTR (SNP) | VAF 102/352 reads (29%) | catalogued as rs764030062; called by muse, mutect2, varscan2
- SNX24 | c.*798C>A | 3'UTR (SNP) | VAF 14/54 reads (26%) | catalogued as rs1478186547; called by muse, mutect2, varscan2
- SPAST | c.*775C>G | 3'UTR (SNP) | VAF 11/139 reads (8%) | called by muse, mutect2
- ST6GAL2 | c.*2187A>T | 3'UTR (SNP) | VAF 7/69 reads (10%) | called by muse, mutect2
- STMP1 | c.*657G>A | 3'UTR (SNP) | VAF 61/134 reads (46%) | catalogued as rs1034964428; called by muse, mutect2, varscan2
- THAP5 | c.80+1044G>A | Intron (SNP) | VAF 16/48 reads (33%) | called by muse, mutect2, varscan2
- TMEM116 | c.-199+1617C>T | Intron (SNP) | VAF 4/13 reads (31%) | called by muse, mutect2
- TMEM8B | c.*98T>G | 3'UTR (SNP) | VAF 13/197 reads (7%) | called by muse, mutect2
- TNNT2 | c.*72G>A | 3'UTR (SNP) | VAF 16/109 reads (15%) | called by muse, mutect2, varscan2
- TRIM64B | c.*205G>A | 3'UTR (SNP) | VAF 58/280 reads (21%) | called by muse, mutect2, varscan2
- UBE2J1 | c.-139C>G | 5'UTR (SNP) | VAF 13/28 reads (46%) | called by muse, mutect2, varscan2
- UCHL3 | c.475-4801G>A | Intron (SNP) | VAF 37/83 reads (45%) | catalogued as rs890767873; called by muse, mutect2, varscan2
- WDR33 | c.725-11067A>T | Intron (SNP) | VAF 55/170 reads (32%) | called by muse, mutect2, varscan2
